Gene-level copy-number profile of tumor specimen TCGA-85-7710-01A from TCGA case TCGA-85-7710, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 59.7 years (21,790 days).
Specimen TCGA-85-7710-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.5c352c10-ae6a-43d9-98a6-c4c97cdb647d.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-7710-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/eaa4cba6-ca6e-4f66-9d16-689f33119aaf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 12,471; copy number 2: 41,075; copy number 3: 3,759; copy number 4: 2,356; copy number 5: 12; copy number 8: 141.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-7710-01A-11D-2121-01): tumor purity 0.73, ploidy 1.9, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 153 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:101,963,901–102,513,655, 12 genes, copy number 5: NENFP2, WASHC3, AC079907.1, NUP37, PARPBP, PMCH, HELLPAR, RN7SL793P, AC093023.1, LINC02456, IGF1, AC010202.1.
- chr17:17,674,026–19,868,689, 141 genes, copy number 8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 11,731. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
